Somatic mutation profile of tumor specimen TCGA-XK-AAIW-01A (aliquot TCGA-XK-AAIW-01A-11D-A41K-08) from TCGA case TCGA-XK-AAIW, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 78.6 years (28,721 days).
Specimen TCGA-XK-AAIW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c5ea3e1-f1ed-4aab-8ca8-7975ff42e443.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XK-AAIW-10A (Blood Derived Normal), aliquot TCGA-XK-AAIW-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ed651fe-63d8-4059-94a3-2a16639877f3

The open-access MAF lists 8,243 somatic variants for this specimen: 5,760 protein-altering or splice-affecting, 2,306 silent, 177 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5,186, Silent 2,306, Nonsense Mutation 320, Splice Site 89, Intron 80, Splice Region 58, Frame Shift Del 52, Frame Shift Ins 48, RNA 40, 3'UTR 28, 5'UTR 13, 5'Flank 8.

Variants (750 of 8,243; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.2842C>T p.R948C | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1559183717, CM081493, COSV55602700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.3124G>A p.G1042S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555509477, CM061627, COSV99229699; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARG1 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs104893948, CM920105, CM962599, CX165256, COSV51580679; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BBS12 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as rs121918327, CM070035, COSV58561593; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL7A1 | c.5532+1G>A p.X1844_splice | Splice Site (SNP) | VAF 15/30 reads (50%) | catalogued as rs767182886, CS120668, CS991356, COSV100097794; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYP4V2 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199476201, CM114000, COSV101114927; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDX11 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as rs781413815, COSV99300351; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLB1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192732174, CM000711, CM056963, COSV56568961; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HNF1B | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs914046953; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IFT172 | c.4630C>T p.R1544C | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587777079, CM1311187, COSV53139911; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNJ2 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199473373, CM066888, COSV54664479; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- KIT | c.2663G>A p.R888Q | Missense Mutation (SNP) | VAF 17/67 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs776681643, COSV55391670, COSV99855011; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KMT2A | c.11221C>T p.R3741* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as rs1057520053, COSV63291284; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 20/61 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NEK1 | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 95/234 reads (41%) | catalogued as rs758677637, COSV101455906; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAK3 | c.1300C>T p.R434* (on ENST00000262836 / NM_001324328.2; = p.R419* on NM_002578.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 31/40 reads (78%) | catalogued as rs121434611, CM981458, COSV53273940; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PHGDH | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.527); catalogued as rs764618040, COSV65573170; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIGO | c.2361del p.T788Lfs*25 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs770591449, COSV99956719; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PLA2G6 | c.1427+1G>A p.X476_splice | Splice Site (SNP) | VAF 15/41 reads (37%) | catalogued as rs750939090, CS090239, COSV100140745; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- POLR3B | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | catalogued as rs267608688, CM119262, COSV99943897; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PYGM | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as rs119103255, CM981688, COSV51214780; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs749223640, CM164169, COSV55025690, COSV55027441; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- RPL35A | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as rs116840808, CS087979, COSV99502751; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SDHA | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 53/124 reads (43%) | catalogued as rs771328239, COSV53769941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SELENON | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368074297, CM114823; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SPTA1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918642, CM910358, CM910359, COSV63752484; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRPV3 | c.1703G>A p.G568D | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057517884, CM1512255, CM1512256, COSV100028194; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.3034C>T p.R1012* (on ENST00000591111; = p.R966* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as rs397517547, CM1410919, COSV59870865; ClinVar: likely pathogenic; called by muse, mutect2
- USH2A | c.14911C>T p.R4971* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as rs397517994, CM1110189, COSV56364393; ClinVar: pathogenic; called by mutect2, varscan2
- VHL | c.464-2A>G p.X155_splice | Splice Site (SNP) | VAF 16/42 reads (38%) | hotspot (GDC flag); catalogued as rs5030816, CS941546, CS961704, CS961705, COSV56547121, COSV56551502, COSV56558899, COSV56563919; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WT1 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 93/185 reads (50%) | catalogued as rs121907909, CM971596, COSV60066326; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZAP70 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137853201, CM016238, COSV53852423; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1307C>A p.P436H (on ENST00000373993 / NM_138932.2; = p.P428H on NM_014576.4) | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV50957418; called by muse, mutect2, varscan2
- A1CF | c.692A>G p.K231R | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.253); catalogued as COSV99258001; called by muse, mutect2
- A1CF | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.485); catalogued as rs775569138, COSV50987018; called by muse, mutect2, varscan2
- A4GALT | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs768921574, COSV99966795; called by muse, varscan2
- AADACL3 | c.1119G>T p.E373D | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV100206910; called by muse, mutect2, varscan2
- AADACL4 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV100879507; called by muse, mutect2, varscan2
- AAR2 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs747683964, COSV100299444; called by muse, mutect2, varscan2
- AARS2 | c.1735G>A p.V579M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.776); catalogued as COSV99771711; called by muse, mutect2, varscan2
- AARS2 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99771712; called by muse, mutect2, varscan2
- ABAT | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs761782312, COSV51628589; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA1 | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.078); catalogued as COSV101037714; called by muse, mutect2, varscan2
- ABCA13 | c.5003G>A p.R1668H | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs566240276, COSV70028171; called by muse, mutect2, varscan2
- ABCA13 | c.14406C>A p.Y4802* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | catalogued as rs778375310; called by muse, varscan2
- ABCA2 | c.1879G>A p.A627T (on ENST00000614293; = p.A597T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as rs1310315285, COSV99688505; called by muse, mutect2, varscan2
- ABCA3 | c.4387C>T p.Q1463* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV57049510; called by muse, mutect2, varscan2
- ABCA3 | c.3250C>A p.L1084M | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV100069154; called by muse, mutect2, varscan2
- ABCA4 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as rs764311517, COSV64678314; called by muse, mutect2, varscan2
- ABCA6 | c.2132G>A p.S711N | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52635824, COSV52643863; called by muse, mutect2, varscan2
- ABCA7 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as COSV99566717; called by muse, mutect2, varscan2
- ABCA7 | c.4780C>T p.P1594S | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.086); catalogued as COSV99566720; called by muse, mutect2, varscan2
- ABCB1 | c.3412C>T p.R1138W | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs773597757, COSV55954540; called by muse, mutect2, varscan2
- ABCB1 | c.1147C>T p.H383Y | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs767962530, COSV99714557; called by muse, mutect2, varscan2
- ABCB1 | c.461C>A p.A154D | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV99714560; called by muse, mutect2, varscan2
- ABCB10 | c.1340-2A>G p.X447_splice | Splice Site (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100748079; called by muse, mutect2, varscan2
- ABCB4 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV99711373; called by muse, mutect2, varscan2
- ABCB5 | c.1837C>T p.R613* (on ENST00000404938 / NM_001163941.2; = p.R168* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 33/75 reads (44%) | catalogued as rs750847169, COSV99329867; called by muse, mutect2, varscan2
- ABCB8 | c.2110G>A p.A704T (on ENST00000297504 / NM_001282291.2; = p.A687T on NM_007188.5) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs778555833, COSV52509320; called by muse, mutect2, varscan2
- ABCC1 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1264102348, COSV60685214; called by muse, mutect2, varscan2
- ABCC11 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100751178; called by muse, mutect2, varscan2
- ABCC11 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs750296570, COSV62321425; called by muse, mutect2, varscan2
- ABCC12 | c.1921G>A p.V641I | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200400469, COSV60916336; called by muse, mutect2, varscan2
- ABCC12 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as rs543162145, COSV100252768; called by muse, mutect2, varscan2
- ABCC5 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs550542220, COSV55589847, COSV55597043; called by mutect2, varscan2
- ABCC8 | c.3938G>A p.R1313H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372153432, CM077499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC8 | c.1818C>T p.S606= | Splice Region (SNP) | VAF 24/39 reads (62%) | catalogued as rs202207978; called by muse, mutect2, varscan2
- ABCC8 | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100217771; called by muse, mutect2, varscan2
- ABCF1 | c.1060C>A p.L354M (on ENST00000326195 / NM_001025091.2; = p.L316M on NM_001090.3) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100401104; called by muse, mutect2, varscan2
- ABCG2 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755591361, COSV52944852; called by muse, mutect2, varscan2
- ABCG4 | c.730A>G p.K244E | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs1456745292, COSV100267068; called by muse, mutect2, varscan2
- ABCG4 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs750791458, COSV56642065; called by muse, mutect2, varscan2
- ABHD16A | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV101013374; called by muse, mutect2, varscan2
- ABHD17B | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV100330310; called by muse, mutect2
- ABHD17C | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.327); catalogued as COSV51918012; called by muse, mutect2, varscan2
- ABHD2 | c.977G>A p.C326Y | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100756482; called by muse, mutect2, varscan2
- ABI1 | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as COSV100698110; called by muse, mutect2, varscan2
- ABI3BP | c.2834G>T p.R945I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs751018251, COSV99428698; called by muse, mutect2, varscan2
- ABL1 | c.3023C>T p.T1008I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100584685; called by muse, mutect2, varscan2
- ABLIM1 | c.758G>A p.C253Y | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99522796; called by muse, mutect2, varscan2
- ABO | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs1444232833; called by muse, mutect2
- ABR | c.122del p.P41Rfs*51 | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | catalogued as COSV56843924; called by mutect2, pindel, varscan2
- ABTB1 | c.560A>G p.D187G (on ENST00000232744 / NM_172027.3; = p.D45G on NM_032548.3) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99230171; called by muse, varscan2
- AC098582.1 | c.642G>A p.W214* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99986079; called by muse, mutect2, varscan2
- AC109583.1 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs1394158343, COSV58406286; called by muse, mutect2, varscan2
- AC127029.3 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM014004, COSV100033365; called by muse, mutect2, varscan2
- ACACA | c.3151C>T p.R1051* | Nonsense Mutation (SNP) | VAF 33/95 reads (35%) | catalogued as rs753014287; called by muse, mutect2, varscan2
- ACACB | c.2047T>C p.Y683H | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV100623322; called by muse, varscan2
- ACAD10 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs770109466, COSV100564655; called by muse, mutect2, varscan2
- ACAD10 | c.2882C>T p.A961V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs146750873; called by muse, mutect2, varscan2
- ACAN | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100719369; called by muse, mutect2, varscan2
- ACAP2 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100462781; called by muse, mutect2, varscan2
- ACAP2 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as rs763853925, COSV58757202; called by muse, mutect2, varscan2
- ACAT1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1190813667, COSV99759442; called by muse, mutect2, varscan2
- ACIN1 | c.3721C>T p.R1241W | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); catalogued as COSV99400391; called by muse, mutect2, varscan2
- ACIN1 | c.3523C>T p.R1175C | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV99400399; called by muse, varscan2
- ACIN1 | c.3463C>T p.R1155W | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as rs1445579735, COSV99400404; called by muse, varscan2
- ACKR1 | c.401G>A p.C134Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.156); catalogued as COSV100929676; called by muse, mutect2, varscan2
- ACKR2 | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 7/93 reads (8%) | catalogued as COSV99825784; called by muse, mutect2
- ACLY | c.1341G>A p.T447= | Splice Region (SNP) | VAF 3/10 reads (30%) | catalogued as rs1555630716, COSV100709653; called by muse, varscan2
- ACLY | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100709920; called by muse, mutect2, varscan2
- ACOX1 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140541455; called by muse, mutect2, varscan2
- ACOX2 | c.1573G>A p.G525R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.965); catalogued as rs759243203, COSV100250317; called by muse, mutect2, varscan2
- ACOX2 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.1); catalogued as rs1337986864, COSV100250318; called by muse, varscan2
- ACP3 | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100313606; called by muse, mutect2, varscan2
- ACSL1 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | catalogued as rs760880493, COSV99861007; called by muse, mutect2, varscan2
- ACSL5 | c.1498G>A p.V500M (on ENST00000354273; = p.V556M on NM_016234.3) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs769134957, COSV100634822; called by muse, mutect2, varscan2
- ACSL6 | c.592G>A p.V198M (on ENST00000379240; = p.V223M on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs368653510; called by muse, varscan2
- ACSM2A | c.197G>A p.S66N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99525767; called by muse, mutect2, varscan2
- ACSM3 | c.430G>T p.G144W | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99185030; called by muse, mutect2, varscan2
- ACTBL2 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 30/57 reads (53%) | catalogued as rs1358229735, COSV101379422; called by muse, mutect2, varscan2
- ACTL6A | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101199747; called by muse, mutect2, varscan2
- ACTN2 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as COSV100857067; called by muse, mutect2, varscan2
- ACTN3 | c.2067G>T p.E689D | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.459); catalogued as rs1351068216, COSV100074512; called by muse, mutect2, varscan2
- ACTN4 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768656011, COSV99400777; called by muse, mutect2, varscan2
- ACTN4 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99400778; called by muse, mutect2, varscan2
- ACTN4 | c.2672C>T p.A891V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99400780; called by muse, mutect2, varscan2
- ACTR1A | c.727C>A p.L243M | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV100883738; called by muse, mutect2, varscan2
- ACTR3B | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1162816026, COSV55447175, COSV99753974; called by muse, mutect2, varscan2
- ACVR1B | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282697245, COSV57777430, COSV99232020; called by muse, mutect2, varscan2
- ADAM15 | c.348C>A p.N116K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV99665373; called by muse, mutect2, varscan2
- ADAM15 | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV99665374; called by muse, mutect2, varscan2
- ADAM18 | c.1510A>G p.K504E | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99696153; called by muse, mutect2, varscan2
- ADAM22 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs760730972, COSV99718452; called by muse, mutect2, varscan2
- ADAM28 | c.2164G>A p.V722I | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99739949; called by muse, mutect2, varscan2
- ADAM29 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100822266; called by muse, mutect2, varscan2
- ADAM30 | c.1715C>T p.T572M | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as rs367708640; called by muse, mutect2, varscan2
- ADAM7 | c.1842+1G>A p.X614_splice | Splice Site (SNP) | VAF 15/44 reads (34%) | catalogued as COSV99445157; called by muse, mutect2, varscan2
- ADAMTS1 | c.1079A>G p.D360G | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV99536563; called by muse, mutect2, varscan2
- ADAMTS10 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54357695, COSV99547472; called by muse, mutect2, varscan2
- ADAMTS10 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782567931, COSV54351680; called by muse, mutect2, varscan2
- ADAMTS13 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100747237; called by muse, mutect2, varscan2
- ADAMTS16 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs371654781; called by muse, mutect2, varscan2
- ADAMTS16 | c.3602C>G p.P1201R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99943212; called by muse, mutect2, varscan2
- ADAMTS17 | c.2780C>T p.A927V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs756721876, COSV99171736; called by muse, mutect2, varscan2
- ADAMTS17 | c.2530C>T p.P844S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs758345120, COSV99171739; called by muse, mutect2, varscan2
- ADAMTS19 | c.803C>T p.T268I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); catalogued as COSV99183489; called by muse, mutect2, varscan2
- ADAMTS20 | c.3887A>T p.N1296I | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.936); catalogued as COSV101166417, COSV67133903; called by muse, mutect2, varscan2
- ADAMTS20 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.052); catalogued as rs767895763, COSV101240454; called by muse, varscan2
- ADAMTS4 | c.1220G>A p.C407Y | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100917580; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2659G>A p.V887I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs969369703; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4183G>A p.V1395I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs762478236, COSV99721400; called by muse, mutect2, varscan2
- ADAR | c.3521G>A p.R1174H | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs866441514, COSV52712997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADARB2 | c.1439T>C p.L480P | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as COSV101187361; called by muse, mutect2, varscan2
- ADCY2 | c.1178G>A p.C393Y | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100604279; called by muse, mutect2, varscan2
- ADCY2 | c.3265G>A p.V1089M | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.018); catalogued as rs200555888, COSV100604282; called by muse, mutect2, varscan2
- ADCY4 | c.2533G>A p.V845M | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.442); catalogued as rs757514372, COSV100156889; called by muse, mutect2, varscan2
- ADCY5 | c.3293G>A p.R1098Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100568306; called by muse, varscan2
- ADCY8 | c.1889A>G p.D630G | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV99654578; called by muse, mutect2, varscan2
- ADCY8 | c.724C>A p.L242M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV99654579; called by muse, mutect2
- ADCY9 | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs912752455, COSV53578739; called by muse, mutect2, varscan2
- ADD2 | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1553368436, COSV100035775; called by muse, mutect2, varscan2
- ADGRA1 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as rs1333925292, COSV100811046; called by muse, mutect2
- ADGRA2 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as rs376864601; called by muse, varscan2
- ADGRB1 | c.3655G>A p.A1219T | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1273962372, COSV60103955; called by muse, mutect2, varscan2
- ADGRB2 | c.2540G>A p.R847H | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs993522337, COSV99926454; called by muse, varscan2
- ADGRB2 | c.574A>G p.N192D | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV99926980; called by muse, mutect2, varscan2
- ADGRE2 | c.674G>A p.S225N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100216539; called by muse, mutect2, varscan2
- ADGRF3 | c.365C>T p.A122V (on ENST00000311519 / NM_001145168.1; = p.A63V on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs180836893, COSV100275490; called by muse, varscan2
- ADGRF5 | c.1992G>A p.G664= | Splice Region (SNP) | VAF 25/65 reads (38%) | catalogued as COSV51941052; called by muse, mutect2, varscan2
- ADGRL1 | c.1960G>A p.V654I (on ENST00000340736 / NM_001008701.3; = p.V649I on NM_014921.5) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs984568735, COSV61565950; called by muse, mutect2, varscan2
- ADGRL2 | c.3404G>A p.R1135H (on ENST00000370717 / NM_001366005.1; = p.R1122H on NM_012302.4) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779502306, COSV54680274, COSV99591631; called by muse, mutect2, varscan2
- ADGRL2 | c.4125G>A p.M1375I (on ENST00000370717 / NM_001366005.1; = p.M1319I on NM_012302.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs1314069626, COSV99591749; called by muse, mutect2, varscan2
- ADGRV1 | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs757860505, CM1514169, COSV67986933; called by muse, mutect2, varscan2
- ADGRV1 | c.17107C>T p.R5703C | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs761963239, COSV67981620; called by muse, mutect2
- ADH1A | c.206A>T p.E69V | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV52925102, COSV99266002; called by muse, mutect2, varscan2
- ADH6 | c.963A>G p.G321= | Splice Region (SNP) | VAF 32/70 reads (46%) | catalogued as rs760721518, COSV99422913; called by muse, mutect2, varscan2
- ADIPOR1 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs1485692750, COSV61851133; called by muse, mutect2, varscan2
- ADORA1 | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.842); catalogued as COSV100526731, COSV58810693; called by muse, mutect2, varscan2
- ADORA3 | c.44A>G p.Y15C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99598906; called by muse, mutect2, varscan2
- ADRA2B | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101337393; called by muse, mutect2, varscan2
- ADRA2C | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs776934062, COSV57468236; called by mutect2, varscan2
- ADSL | c.911G>A p.C304Y | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99342614; called by muse, mutect2, varscan2
- ADSS2 | c.1339A>G p.K447E | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV100836916; called by muse, mutect2, varscan2
- ADTRP | c.659-1G>T p.X220_splice | Splice Site (SNP) | VAF 39/73 reads (53%) | catalogued as COSV99995545; called by muse, mutect2, varscan2
- AEBP1 | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs774295668, COSV56261098, COSV99788475; called by muse, mutect2, varscan2
- AEN | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.68); catalogued as COSV100237585; called by muse, mutect2, varscan2
- AFAP1 | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs1311126342, COSV100632251; called by muse, mutect2, varscan2
- AFAP1 | c.1531C>T p.L511F | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1362857068, COSV100632255; called by muse, mutect2, varscan2
- AFDN | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as rs764123133, COSV60045170; called by muse, mutect2, varscan2
- AFDN | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780592632, COSV100653602; called by muse, mutect2, varscan2
- AFF3 | c.3089C>T p.T1030M | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as rs530073150, COSV57848496; called by muse, mutect2, varscan2
- AFF3 | c.1924C>T p.R642C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs780233607, COSV57876679; called by muse, mutect2, varscan2
- AFF3 | c.620G>A p.S207N | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100420176; called by muse, mutect2, varscan2
- AFM | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV99889297; called by muse, mutect2, varscan2
- AGAP2 | c.3076T>A p.S1026T (on ENST00000547588 / NM_001122772.2; = p.S670T on NM_014770.4) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.101); catalogued as COSV99224369; called by muse, mutect2, varscan2
- AGAP4 | c.1879G>A p.V627I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV71164803; called by mutect2, varscan2
- AGBL1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs182802715, COSV69797597; called by muse, mutect2, varscan2
- AGBL5 | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.655); catalogued as COSV100549457; called by muse, mutect2, varscan2
- AGFG1 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs142955065; called by muse, mutect2, varscan2
- AGL | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99650105; called by muse, mutect2, varscan2
- AGO1 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV100940931; called by muse, mutect2, varscan2
- AGO3 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.12); catalogued as rs777420347, COSV99867899; called by muse, mutect2, varscan2
- AGPAT4 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs141441479; called by muse, mutect2, varscan2
- AGR2 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV101290834; called by muse, mutect2, varscan2
- AGRN | c.5093G>A p.R1698H | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs551658645, COSV101039126; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGTPBP1 | c.1358G>A p.R453H (on ENST00000357081 / NM_001330701.2; = p.R413H on NM_015239.2) | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.361); catalogued as rs1457551466, COSV61271241; called by muse, mutect2, varscan2
- AGTPBP1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100430316; called by muse, mutect2, varscan2
- AGTR1 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); catalogued as rs757827237, COSV62559689; called by muse, mutect2, varscan2
- AHCY | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs116262714, COSV54153808; called by muse, mutect2, varscan2
- AHCYL1 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100779686; called by muse, mutect2, varscan2
- AHCYL1 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1265315243, COSV63208875; called by muse, mutect2, varscan2
- AHDC1 | c.4237C>T p.R1413W | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs777716141, COSV99899777; called by muse, mutect2, varscan2
- AHDC1 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.25); catalogued as COSV99899780; called by muse, mutect2, varscan2
- AHI1 | c.3364C>T p.R1122* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as rs1487081231, COSV55630779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHNAK | c.10918G>A p.V3640I | Missense Mutation (SNP) | VAF 97/238 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747814282, COSV57210949; called by muse, varscan2
- AHNAK | c.7330C>T p.P2444S | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99949787; called by muse, mutect2, varscan2
- AHNAK | c.3113C>T p.A1038V | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV99949789; called by muse, mutect2, varscan2
- AHNAK2 | c.10760G>A p.G3587D | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.962); catalogued as COSV100319073; called by muse, mutect2, varscan2
- AHNAK2 | c.10460C>T p.A3487V | Missense Mutation (SNP) | VAF 105/286 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV100319075; called by muse, mutect2, varscan2
- AHNAK2 | c.9289G>A p.V3097M | Missense Mutation (SNP) | VAF 84/195 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1261399340, COSV100319077; called by muse, mutect2, varscan2
- AHNAK2 | c.3685G>A p.V1229M | Missense Mutation (SNP) | VAF 54/63 reads (86%) | SIFT tolerated (0.31); PolyPhen benign (0.151); catalogued as rs371284486, COSV100319079; called by muse, mutect2, varscan2
- AHNAK2 | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as COSV100319080; called by muse, mutect2, varscan2
- AICDA | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV57563759; called by muse, mutect2, varscan2
- AIFM2 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs750119679, COSV100325838; called by muse, mutect2, varscan2
- AJM1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1327655266, COSV56034349; called by muse, varscan2
- AK2 | c.299G>T p.R100M (on ENST00000354858; = p.R142M on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100710088; called by muse, mutect2, varscan2
- AK7 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as rs750684821, COSV99967325; called by muse, mutect2, varscan2
- AK8 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.509); catalogued as rs753799831, COSV100050575; called by muse, mutect2, varscan2
- AKAP1 | c.2120G>A p.G707D | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100533182; called by muse, mutect2, varscan2
- AKAP13 | c.4822G>A p.G1608R (on ENST00000394518 / NM_007200.5; = p.G1612R on NM_006738.6) | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1336598913, COSV100774745; called by muse, mutect2, varscan2
- AKAP13 | c.6598C>T p.R2200C (on ENST00000394518 / NM_007200.5; = p.R2204C on NM_006738.6) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63450117; called by muse, mutect2, varscan2
- AKAP13 | c.7909C>T p.R2637W (on ENST00000394518 / NM_007200.5; = p.R2641W on NM_006738.6) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs758809249, COSV100774746; called by muse, varscan2
- AKAP13 | c.7963C>T p.R2655C (on ENST00000394518 / NM_007200.5; = p.R2659C on NM_006738.6) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1448656405, COSV63465796; called by muse, varscan2
- AKAP6 | c.31del p.L11* | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | catalogued as rs771895850; called by mutect2, pindel, varscan2
- AKAP8L | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.54); catalogued as COSV101275885; called by muse, mutect2, varscan2
- AKAP9 | c.1329G>T p.Q443H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100663189; called by muse, mutect2, varscan2
- AKAP9 | c.7589G>A p.S2530N (on ENST00000359028; = p.S2506N on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV100663197; called by muse, mutect2, varscan2
- AKAP9 | c.7976del p.N2659Mfs*3 (on ENST00000359028; = p.N2635Mfs*3 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | catalogued as rs1250599910; called by mutect2, pindel, varscan2
- AKNAD1 | c.1918C>T p.H640Y | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100645907; called by muse, mutect2, varscan2
- AKR1C1 | c.252+2T>G p.X84_splice | Splice Site (SNP) | VAF 29/74 reads (39%) | catalogued as COSV101080582; called by muse, mutect2, varscan2
- AKR7A2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.275); catalogued as rs964449864, COSV52516930; called by muse, mutect2, varscan2
- AKT1S1 | c.592A>G p.T198A (on ENST00000344175 / NM_001098633.4; = p.T218A on NM_032375.5) | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100465710; called by muse, mutect2, varscan2
- AL136295.1 | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768120763, COSV55779581, COSV55782983; called by muse, mutect2, varscan2
- AL162417.1 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.439); catalogued as COSV100923174; called by muse, mutect2, varscan2
- AL645922.1 | c.2971G>A p.D991N | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.6); catalogued as rs1229029793, COSV100191522; called by muse, varscan2
- AL645922.1 | c.2991G>A p.W997* | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | catalogued as COSV100190495, COSV54960291; called by muse, varscan2
- ALAS1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59628805; called by muse, varscan2
- ALAS1 | c.936C>A p.C312* | Nonsense Mutation (SNP) | VAF 36/85 reads (42%) | catalogued as COSV100050504; called by muse, varscan2
- ALDH1A2 | c.545A>G p.Q182R | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99991139; called by muse, mutect2, varscan2
- ALDH1B1 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100891007; called by muse, mutect2, varscan2
- ALDH1L2 | c.429-1G>T p.X143_splice | Splice Site (SNP) | VAF 15/42 reads (36%) | catalogued as rs1273182640, COSV99311348; called by muse, mutect2, varscan2
- ALDH4A1 | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs144311914; called by muse, mutect2, varscan2
- ALDH6A1 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100620969; called by muse, mutect2, varscan2
- ALDH6A1 | c.763A>G p.K255E | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV100620970; called by muse, mutect2, varscan2
- ALDH8A1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs188218462, COSV55643764; called by muse, mutect2, varscan2
- ALDOC | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99257309; called by muse, mutect2, varscan2
- ALG10B | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100440025; called by muse, mutect2, varscan2
- ALG10B | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100440027; called by muse, varscan2
- ALG9 | c.1831G>T p.G611C (on ENST00000614444 / NM_001352418.1; = p.G618C on NM_024740.2) | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as COSV101211951; called by muse, varscan2
- ALKBH1 | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.824); catalogued as COSV99380805; called by muse, mutect2, varscan2
- ALMS1 | c.3473C>T p.A1158V | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as COSV100043874; called by muse, mutect2, varscan2
- ALOX12 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as rs754344753, COSV99278492; called by mutect2, varscan2
- ALOX12B | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100047786; called by muse, mutect2, varscan2
- ALOX15 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs917942648, COSV53398456; called by muse, mutect2, varscan2
- ALOX5 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779128700, COSV100980214; called by muse, mutect2, varscan2
- ALPK1 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV99455249; called by muse, mutect2, varscan2
- ALPK2 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as rs781442098, COSV100864845; called by muse, mutect2, varscan2
- ALPK2 | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV100864846; called by muse, mutect2, varscan2
- ALS2 | c.4141C>T p.H1381Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99970105; called by muse, mutect2, varscan2
- ALS2 | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1158688450, COSV99970108; called by muse, mutect2, varscan2
- ALX4 | c.1197G>T p.K399N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100241333; called by muse, varscan2
- AMBRA1 | c.1178G>A p.R393H (on ENST00000458649 / NM_001367468.1; = p.R303H on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as rs773779272, COSV100095420; called by muse, mutect2
- AMER1 | c.2749G>A p.E917K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV100367092; called by muse, mutect2, varscan2
- AMER3 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.73); catalogued as rs777830044, COSV100366940; called by muse, mutect2, varscan2
- AMIGO3 | c.1407G>T p.Q469H | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as rs149938600; called by muse, varscan2
- AMMECR1L | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as rs756760101, COSV55761947; called by muse, mutect2, varscan2
- AMOT | c.1928G>A p.R643H (on ENST00000371959 / NM_001113490.1; = p.R234H on NM_133265.3) | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1162432848, COSV100495593; called by muse, mutect2, varscan2
- AMPD1 | c.1796C>T p.T599M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781393982, COSV62416081; called by muse, mutect2, varscan2
- AMPD1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs140601541, COSV100814850; called by muse, mutect2, varscan2
- AMPD2 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as rs749468757, COSV56646171; called by muse, mutect2, varscan2
- AMZ1 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.37); catalogued as rs201114825, COSV100406620; called by muse, mutect2, varscan2
- ANAPC1 | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100595130; called by muse, mutect2, varscan2
- ANAPC2 | c.1730A>G p.E577G | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1418835089, COSV100119251; called by muse, mutect2, varscan2
- ANAPC2 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV100119253; called by muse, mutect2, varscan2
- ANAPC7 | c.1237C>T p.L413F | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV101482878; called by muse, mutect2, varscan2
- ANGEL1 | c.1840G>A p.G614R | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs762821195, COSV99200497; called by muse, mutect2, varscan2
- ANGEL1 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776392389, COSV99200406, COSV99200499; called by muse, mutect2, varscan2
- ANGPT1 | c.398G>A p.S133N | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs559521639; called by muse, mutect2, varscan2
- ANGPTL2 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.402); catalogued as rs138716830; called by muse, mutect2, varscan2
- ANK1 | c.3964C>T p.R1322C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs1202247842, COSV99227002; called by muse, mutect2, varscan2
- ANK1 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs779607492, COSV55875316, COSV55876374; called by muse, mutect2
- ANK1 | c.854T>C p.V285A | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.046); catalogued as COSV99227005; called by muse, mutect2, varscan2
- ANK2 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1458712708, COSV100004416; called by muse, varscan2
- ANK2 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs752016285, COSV52146942, COSV52147138; ClinVar: uncertain significance; called by muse, varscan2
- ANK2 | c.6125C>T p.A2042V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100004424; called by muse, mutect2, varscan2
- ANK2 | c.7791G>A p.M2597I | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.033); catalogued as COSV100004428; called by muse, mutect2, varscan2
- ANK2 | c.8239C>A p.R2747S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs376628082, COSV100004430; called by muse, mutect2, varscan2
- ANK2 | c.8665G>A p.D2889N | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as COSV100004431; called by muse, mutect2, varscan2
- ANK3 | c.3985C>T p.R1329* (on ENST00000280772 / NM_001320874.2; = p.R463* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 64/141 reads (45%) | catalogued as COSV55051656; called by muse, mutect2, varscan2
- ANKAR | c.1685G>T p.R562M | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99854710; called by muse, mutect2, varscan2
- ANKAR | c.4181A>C p.N1394T | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as COSV99854722; called by muse, mutect2, varscan2
- ANKDD1A | c.1376G>A p.G459D | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs534249413, COSV100731290; called by muse, mutect2, varscan2
- ANKFN1 | c.1914C>A p.C638* | Nonsense Mutation (SNP) | VAF 12/109 reads (11%) | catalogued as COSV100594270; called by muse, mutect2
- ANKFY1 | c.1975C>A p.L659I (on ENST00000341657 / NM_001330063.2; = p.L660I on NM_016376.5) | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs1440428546, COSV100493206; called by muse, mutect2, varscan2
- ANKFY1 | c.62T>C p.V21A | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as rs1163555800, COSV100493207; called by muse, mutect2, varscan2
- ANKH | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.996); catalogued as COSV99415960; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.615C>T p.D205= | Splice Region (SNP) | VAF 35/86 reads (41%) | catalogued as rs766488772, COSV99784594; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5603G>A p.R1868Q | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs780252120, COSV99784602; called by muse, mutect2, varscan2
- ANKK1 | c.1589C>A p.P530Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1328698881, COSV100393098; called by muse, mutect2, varscan2
- ANKLE2 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs1346187941, COSV100514380; called by muse, mutect2, varscan2
- ANKLE2 | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746049596, COSV100514381; called by muse, mutect2, varscan2
- ANKLE2 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1277337025, COSV61710676; called by muse, mutect2, varscan2
- ANKRD11 | c.2581C>T p.P861S | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.702); catalogued as COSV99970725; called by muse, mutect2, varscan2
- ANKRD12 | c.2588G>A p.C863Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.259); catalogued as rs1185278807, COSV100042179; called by muse, mutect2, varscan2
- ANKRD13C | c.713C>A p.P238H | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52029484, COSV99257749; called by muse, mutect2, varscan2
- ANKRD23 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100450553; called by muse, mutect2, varscan2
- ANKRD26 | c.2420C>T p.T807M | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs955032293, COSV65776812; called by muse, mutect2, varscan2
- ANKRD26 | c.1493C>A p.P498H | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101066661; called by muse, mutect2, varscan2
- ANKRD26 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV101066662; called by muse, mutect2, varscan2
- ANKRD27 | c.2949G>T p.Q983H | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100043193; called by muse, mutect2, varscan2
- ANKRD27 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 62/295 reads (21%) | catalogued as rs750108112, COSV60131567; called by muse, mutect2, varscan2
- ANKRD44 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as rs762390824, COSV56550727; called by muse, varscan2
- ANKRD49 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs1361548385, COSV57059778; called by muse, mutect2, varscan2
- ANKRD52 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); catalogued as rs1386191599, COSV57287457; called by muse, varscan2
- ANKRD52 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99920971; called by muse, mutect2, varscan2
- ANKRD6 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs747090603, COSV60229141; called by muse, mutect2, varscan2
- ANKS1A | c.2915C>T p.T972M | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319209681, COSV100832251; called by muse, mutect2, varscan2
- ANKS1B | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100248312, COSV61348985; called by muse, mutect2, varscan2
- ANKS1B | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748145482, COSV100248315; called by muse, mutect2, varscan2
- ANKS4B | c.971G>A p.G324D | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100289969; called by muse, mutect2, varscan2
- ANO1 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776046934, COSV60283039; called by muse, mutect2, varscan2
- ANO1 | c.2633A>G p.D878G | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.439); catalogued as COSV100797522; called by muse, mutect2, varscan2
- ANO4 | c.571T>C p.Y191H (on ENST00000392977 / NM_001286615.2; = p.Y156H on NM_178826.4) | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.035); catalogued as rs765934326, COSV100153910; called by muse, mutect2, varscan2
- ANO6 | c.910T>C p.Y304H | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100263992; called by muse, mutect2, varscan2
- ANO9 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as rs1172720468, COSV100230324; called by muse, mutect2, varscan2
- ANOS1 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99391482; called by muse, mutect2, varscan2
- ANP32D | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99874225; called by muse, mutect2, varscan2
- ANTXR1 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.328); catalogued as rs376960445; called by muse, mutect2, varscan2
- ANXA4 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 48/100 reads (48%) | catalogued as COSV101268844; called by muse, mutect2, varscan2
- AOC3 | c.607C>T p.H203Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV99520427; called by muse, mutect2, varscan2
- AP1AR | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1363579469, COSV99914319; called by muse, mutect2, varscan2
- AP1B1 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1245595086, COSV100434853; called by muse, mutect2, varscan2
- AP1G2 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs748127582, COSV55338027; called by muse, mutect2, varscan2
- AP1M1 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV99358693; called by muse, mutect2, varscan2
- AP1M1 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 13/21 reads (62%) | catalogued as COSV99358696; called by muse, mutect2, varscan2
- AP2A1 | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.324); catalogued as rs1244689907, COSV100756534; called by muse, mutect2, varscan2
- AP4E1 | c.2566G>A p.E856K | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV99957245; called by muse, mutect2, varscan2
- AP4M1 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs371712994; called by muse, mutect2, varscan2
- AP4M1 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.3); catalogued as rs573143488, COSV100385196; called by muse, mutect2, varscan2
- AP5Z1 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as rs765200689, COSV62240958; called by muse, varscan2
- AP5Z1 | c.1227A>T p.E409D | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.269); catalogued as COSV100804250; called by muse, varscan2
- AP5Z1 | c.2117C>T p.T706M | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs752688603, COSV100804123; called by muse, varscan2
- APAF1 | c.849G>T p.E283D (on ENST00000551964 / NM_181861.2; = p.E272D on NM_001160.3) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV100244456; called by muse, mutect2, varscan2
- APBA1 | c.1968+2T>C p.X656_splice | Splice Site (SNP) | VAF 12/91 reads (13%) | catalogued as COSV99597227; called by muse, mutect2, varscan2
- APBA2 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.483); catalogued as rs575379564, COSV101381956; called by muse, mutect2, varscan2
- APBB1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs766381978, COSV54975389; called by muse, mutect2, varscan2
- APBB1IP | c.1996T>A p.S666T | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100882274; called by muse, mutect2, varscan2
- APBB2 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99924210; called by muse, mutect2, varscan2
- APBB3 | c.400C>A p.L134M | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100021527; called by muse, mutect2, varscan2
- APC2 | c.1565T>C p.I522T | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs1416829812, COSV99279903; called by muse, mutect2, varscan2
- APC2 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs1275265307, COSV99279904; called by muse, mutect2, varscan2
- APEH | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749450590, COSV56535504; called by mutect2, varscan2
- API5 | c.1366G>T p.A456S | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.79); PolyPhen benign (0.015); catalogued as rs1346250131, COSV101124606; called by muse, mutect2, varscan2
- APLNR | c.960C>G p.C320W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99951686; called by muse, mutect2, varscan2
- APLNR | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.974); catalogued as rs147193169, COSV57243545; called by muse, mutect2, varscan2
- APLNR | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs374221224, COSV99951271; called by muse, mutect2
- APLP1 | c.1280C>T p.T427M | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs990841702, COSV55702680, COSV99697966; called by muse, varscan2
- APLP1 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV99697970; called by muse, varscan2
- APOA4 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs1297222124, COSV100759399; called by muse, mutect2, varscan2
- APOA5 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs866269244, COSV99911505; called by muse, mutect2
- APOB | c.12241C>A p.L4081I | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV99268341; called by muse, mutect2, varscan2
- APOB | c.7763C>A p.P2588H | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781471544, COSV99268343; called by muse, mutect2, varscan2
- APOBEC1 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as COSV57549206; called by muse, mutect2, varscan2
- APOBEC3B | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs374260464, COSV100213869; called by muse, mutect2, varscan2
- APOC1 | c.114G>T p.K38N | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99377246; called by muse, mutect2, varscan2
- APOE | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs762461580, COSV99375946, COSV99376305; called by muse, mutect2, varscan2
- APOE | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.09); catalogued as rs1377553244, COSV99376310; called by muse, mutect2, varscan2
- APOO | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as rs373029808, COSV101004914; called by muse, mutect2, varscan2
- AQP9 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs755358483, COSV99582746; called by muse, mutect2, varscan2
- ARAP1 | c.3514G>A p.G1172S (on ENST00000393609 / NM_001040118.2; = p.G927S on NM_015242.4) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs375239868; called by muse, mutect2, varscan2
- ARAP3 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.644); catalogued as rs1178016939, COSV99500337; called by muse, mutect2, varscan2
- AREL1 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs757996581, COSV100707656; called by muse, mutect2, varscan2
- AREL1 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as rs560391293, COSV62666145; called by muse, mutect2, varscan2
- ARF1 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.29); catalogued as rs752069371, COSV55255638; called by muse, mutect2, varscan2
- ARFGEF3 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 87/196 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99294799; called by muse, mutect2, varscan2
- ARFGEF3 | c.2722C>T p.R908W | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs763602394, COSV52450100; called by muse, mutect2, varscan2
- ARHGAP1 | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100358074; called by muse, mutect2, varscan2
- ARHGAP10 | c.1392-1G>T p.X464_splice | Splice Site (SNP) | VAF 67/221 reads (30%) | catalogued as COSV60599845; called by muse, mutect2, varscan2
- ARHGAP12 | c.2487G>T p.Q829H | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1349688615, COSV100260929; called by muse, mutect2, varscan2
- ARHGAP18 | c.1935G>T p.K645N | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs1263665090, COSV100936507; called by muse, mutect2, varscan2
- ARHGAP19 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.541); catalogued as COSV100363358, COSV57393151; called by muse, varscan2
- ARHGAP30 | c.3047G>A p.R1016Q (on ENST00000368013 / NM_001025598.2; = p.R805Q on NM_181720.3) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.559); catalogued as rs775692057, COSV100920523; called by muse, mutect2, varscan2
- ARHGAP31 | c.2495G>A p.S832N | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99957793; called by muse, mutect2, varscan2
- ARHGAP32 | c.6038G>A p.R2013H (on ENST00000310343 / NM_001378025.1; = p.R1664H on NM_014715.4) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.893); catalogued as rs373791354; called by muse, mutect2, varscan2
- ARHGAP32 | c.1058G>A p.R353H (on ENST00000310343 / NM_001378025.1; = p.R4H on NM_014715.4) | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100089470; called by muse, mutect2, varscan2
- ARHGAP33 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1363584324, COSV99140221; called by muse, mutect2, varscan2
- ARHGAP35 | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs780026082, COSV68333417; called by muse, mutect2, varscan2
- ARHGAP44 | c.782T>G p.L261R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99311569; called by muse, mutect2, varscan2
- ARHGAP45 | c.872A>G p.N291S | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs1439332989, COSV100491157; called by muse, mutect2, varscan2
- ARHGAP5 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100565720; called by muse, mutect2, varscan2
- ARHGEF1 | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100529231; called by muse, mutect2, varscan2
- ARHGEF10 | c.2210C>T p.A737V (on ENST00000398564; = p.A712V on NM_014629.4) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs201394769; called by muse, mutect2, varscan2
- ARHGEF10L | c.1044G>T p.E348D | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.248); catalogued as COSV99393912; called by muse, mutect2, varscan2
- ARHGEF12 | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs748466006, COSV63105950; called by muse, mutect2, varscan2
- ARHGEF17 | c.1589C>T p.T530M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.151); catalogued as rs573060878, COSV55229676; called by muse, mutect2, varscan2
- ARHGEF17 | c.4339G>A p.D1447N | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs754857828, COSV99736899; called by muse, mutect2, varscan2
- ARHGEF17 | c.5356G>A p.V1786M | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV99736900; called by muse, mutect2, varscan2
- ARHGEF2 | c.1235G>A p.R412H (on ENST00000361247 / NM_001162383.2; = p.R384H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1356038204, COSV100561226; called by muse, mutect2, varscan2
- ARHGEF2 | c.502C>T p.R168C (on ENST00000361247 / NM_001162383.2; = p.R141C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs770552827, COSV100561227; called by muse, mutect2, varscan2
- ARHGEF25 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs764036012, COSV54086970; called by muse, mutect2, varscan2
- ARHGEF26 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs552521961, COSV100726692; called by muse, mutect2, varscan2
- ARHGEF37 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs372584659; called by muse, mutect2, varscan2
- ARHGEF39 | c.907T>C p.S303P | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs1485343512, COSV100526372, COSV58396491; called by muse, mutect2, varscan2
- ARHGEF4 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1230651357, COSV100388751; called by muse, mutect2, varscan2
- ARHGEF40 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as rs1442827126, COSV100070739; called by muse, mutect2, varscan2
- ARID1A | c.5419A>G p.S1807G | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs1223970955; called by muse, mutect2
- ARID1B | c.4517G>A p.R1506H | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1449208173, COSV51668801; called by muse, mutect2, varscan2
- ARID2 | c.3782G>A p.R1261H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1199501070, COSV57599710; called by muse, mutect2, varscan2
- ARID3B | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.066); catalogued as rs751620803, COSV100654774; called by muse, mutect2, varscan2
- ARID3C | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV99427080; called by muse, mutect2, varscan2
- ARID4A | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100794651; called by muse, mutect2, varscan2
- ARID4A | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs770373766, COSV62162543; called by muse, mutect2, varscan2
- ARID4B | c.2963C>A p.P988H | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.066); catalogued as COSV99936411; called by muse, mutect2, varscan2
- ARID5A | c.657G>T p.Q219H | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as COSV100673657; called by muse, varscan2
- ARID5B | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV54425484, COSV99690532; called by muse, mutect2, varscan2
- ARIH1 | c.842G>A p.C281Y | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101158906, COSV65912600; called by muse, mutect2, varscan2
- ARL6 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as COSV100256615; called by muse, mutect2, varscan2
- ARMC3 | c.1563G>A p.G521= | Splice Region (SNP) | VAF 21/59 reads (36%) | catalogued as rs774401261, COSV53066627, COSV99958947; called by muse, mutect2, varscan2
- ARMC4 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs200127444, COSV59459824; called by muse, mutect2, varscan2
- ARMC6 | c.739C>T p.R247C (on ENST00000392336; = p.R222C on NM_033415.4) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs957697628, COSV54184015; called by muse, mutect2, varscan2
- ARMC9 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs144388331; called by muse, mutect2, varscan2
- ARMC9 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV63022042; called by muse, mutect2
- ARMCX2 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs1556059951, COSV100168006; called by muse, mutect2, varscan2
- ARMCX2 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 40/46 reads (87%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100168321; called by muse, mutect2, varscan2
- ARMCX5 | c.1555A>G p.K519E | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1358925759, COSV99863561; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs780519643, COSV100772001; called by mutect2, varscan2
- ARPIN | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV62590301; called by muse, mutect2, varscan2
- ARPP21 | c.1631C>A p.P544H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99493497; called by muse, mutect2, varscan2
- ARRB1 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs368449308; called by muse, mutect2, varscan2
- ARRDC4 | c.546G>T p.E182D | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.089); catalogued as rs1217656172, COSV99164525; called by muse, mutect2, varscan2
- ARRDC4 | c.730A>G p.T244A | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.415); catalogued as COSV51420258, COSV99164528; called by muse, mutect2, varscan2
- ARRDC4 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.922); catalogued as COSV51419886, COSV99164531; called by muse, mutect2, varscan2
- ARSG | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs756266983, COSV101477884; called by muse, mutect2, varscan2
- ARSI | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100156134; called by muse, mutect2, varscan2
- ARV1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV59617615; called by muse, mutect2, varscan2
- ARVCF | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.707); catalogued as rs1331717847, COSV54267834; called by muse, mutect2, varscan2
- ARVCF | c.433G>T p.G145* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as rs745587564, COSV99599555; called by muse, mutect2, varscan2
- ASAP1 | c.1259C>T p.T420I | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV100727946; called by muse, mutect2, varscan2
- ASB1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs766226125, COSV99223479; called by muse, varscan2
- ASB16 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs144140141; called by muse, mutect2, varscan2
- ASB6 | c.679G>T p.G227W | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV99475858; called by muse, mutect2, varscan2
- ASCC2 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100316526; called by muse, mutect2, varscan2
- ASMTL | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.089); catalogued as rs1299255795, COSV101187904, COSV101187979; called by muse, mutect2, varscan2
- ASNSD1 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99641409; called by muse, mutect2, varscan2
- ASPM | c.3784G>A p.D1262N | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV99661189; called by muse, mutect2, varscan2
- ASPRV1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs777566583, COSV100208645; called by muse, mutect2, varscan2
- ASRGL1 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV100078210; called by muse, varscan2
- ASTE1 | c.1394C>A p.P465H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99394022; called by muse, mutect2, varscan2
- ASTN2 | c.3802C>T p.R1268W (on ENST00000313400 / NM_001365069.1; = p.R1217W on NM_014010.5) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs752542381, COSV99941797; called by muse, mutect2, varscan2
- ASTN2 | c.3661G>A p.A1221T (on ENST00000313400 / NM_001365069.1; = p.A1170T on NM_014010.5) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99941800; called by muse, mutect2, varscan2
- ASXL1 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148964601; called by muse, mutect2, varscan2
- ASXL2 | c.3040C>T p.P1014S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.598); catalogued as COSV99712081; called by muse, mutect2, varscan2
- ATAD2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755251005, COSV54879444; called by muse, mutect2, varscan2
- ATAD3A | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as rs1557484054, COSV100186643; called by muse, mutect2, varscan2
- ATF2 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1391734077, COSV99909044; called by muse, mutect2, varscan2
- ATF3 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100422115; called by muse, mutect2, varscan2
- ATF7IP | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1321285227, COSV53769872; called by muse, mutect2, varscan2
- ATF7IP | c.2825C>A p.A942D | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.12); catalogued as COSV99662167; called by muse, mutect2, varscan2
- ATF7IP2 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs770832333, COSV100202827, COSV100202841; called by muse, mutect2, varscan2
- ATG16L1 | c.401G>A p.C134Y | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1172644391, COSV100731413; called by muse, mutect2, varscan2
- ATG2A | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs375562497; called by muse, mutect2, varscan2
- ATG2A | c.1415T>C p.F472S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV101034841; called by muse, varscan2
- ATG2B | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as COSV100738296; called by muse, mutect2, varscan2
- ATG5 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1457699582, COSV100576690, COSV58349609; called by muse, mutect2, varscan2
- ATG9A | c.683T>C p.L228P | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100772694; called by muse, mutect2, varscan2
- ATG9A | c.148-1C>T p.X50_splice | Splice Site (SNP) | VAF 14/49 reads (29%) | catalogued as rs1247404399, COSV60132699; called by muse, mutect2, varscan2
- ATIC | c.1484T>C p.V495A | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99378235; called by muse, mutect2, varscan2
- ATIC | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99378238; called by muse, mutect2
- ATL2 | c.1487G>A p.G496D | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100185080; called by muse, mutect2, varscan2
- ATP10A | c.1787G>T p.R596M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as COSV100791507, COSV100791573; called by muse, mutect2, varscan2
- ATP11A | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs376242436; called by muse, mutect2, varscan2
- ATP11A | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1417105477, COSV52107059; called by muse, mutect2, varscan2
- ATP11A | c.1552G>A p.V518I | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99370062; called by muse, mutect2, varscan2
- ATP13A1 | c.2242G>T p.G748* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as rs1391866627, COSV99366637; called by muse, mutect2, varscan2
- ATP13A4 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.052); catalogued as rs1408864092, COSV99794581, COSV99795295; called by muse, mutect2
- ATP1A2 | c.1020G>A p.V340= | Splice Region (SNP) | VAF 10/65 reads (15%) | catalogued as rs142140032; called by muse, mutect2
- ATP1A4 | c.2947G>A p.A983T | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); catalogued as rs200603421; called by muse, mutect2, varscan2
- ATP1B2 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as COSV100006976; called by muse, mutect2, varscan2
- ATP2A1 | c.2305G>A p.V769M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs755044339, COSV100707083; called by muse, mutect2, varscan2
- ATP2A3 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs766865638, COSV99989718; called by muse, mutect2, varscan2
- ATP2B1 | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV99666213; called by muse, mutect2, varscan2
- ATP2B3 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as rs782054284, COSV99685986; called by muse, varscan2
- ATP2B3 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as rs373144811, COSV54848526; called by muse, varscan2
- ATP2B3 | c.1405G>T p.A469S | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV99685998; called by muse, varscan2
- ATP2B3 | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782696034, COSV54867238; called by muse, varscan2
- ATP2B4 | c.1997C>T p.A666V | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.384); catalogued as rs556425707, COSV58177498; called by muse, mutect2, varscan2
- ATP2C2 | c.2164G>T p.G722C | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202848944, COSV99298683; called by muse, mutect2, varscan2
- ATP4A | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as rs750384600, COSV99383131; called by muse, mutect2, varscan2
- ATP5F1C | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.399); catalogued as rs758013111, COSV59621773; called by muse, mutect2, varscan2
- ATP5MC1 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs768584646, COSV63506070; called by muse, mutect2, varscan2
- ATP6V0A1 | c.454T>C p.S152P | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.807); catalogued as COSV99231634; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1706A>G p.Y569C | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs749142430, COSV99231638; called by muse, varscan2
- ATP6V0A1 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99231647; called by muse, varscan2
- ATP6V0A2 | c.2359G>A p.V787I | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.177); catalogued as rs374221951; called by muse, mutect2, varscan2
- ATP6V0B | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV99356661; called by muse, mutect2, varscan2
- ATP6V1A | c.1290+1G>A p.X430_splice | Splice Site (SNP) | VAF 18/63 reads (29%) | catalogued as COSV99850432; called by muse, mutect2, varscan2
- ATP7A | c.4415G>A p.R1472H | Missense Mutation (SNP) | VAF 97/134 reads (72%) | SIFT tolerated (0.28); PolyPhen benign (0.231); catalogued as rs1204475767, COSV100431773; called by muse, mutect2, varscan2
- ATP7B | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs1279248478, COSV99666989; called by muse, mutect2, varscan2
- ATP8B2 | c.407G>A p.R136H (on ENST00000672630; = p.R103H on NM_001005855.2) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1197080499, COSV100527989; called by muse, mutect2, varscan2
- ATP8B2 | c.2542G>A p.G848R (on ENST00000672630; = p.G815R on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100528260; called by muse, mutect2, varscan2
- ATP9A | c.2474G>A p.G825D | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.536); catalogued as rs1455403527, COSV100125679; called by muse, mutect2, varscan2
- ATP9A | c.1956G>T p.E652D | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100125680; called by muse, mutect2, varscan2
- ATPAF2 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.393); catalogued as COSV101466962; called by muse, mutect2, varscan2
- ATRNL1 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100369005, COSV100372927; called by muse, mutect2, varscan2
- ATXN1 | c.32G>A p.C11Y | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99787976; called by muse, mutect2, varscan2
- ATXN2 | c.2962C>T p.P988S (on ENST00000550104; = p.P828S on NM_002973.4) | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.388); catalogued as COSV101112910; called by muse, mutect2, varscan2
- ATXN7L2 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV100881372; called by muse, mutect2, varscan2
- AURKC | c.630G>A p.M210I (on ENST00000302804 / NM_001015878.2; = p.M176I on NM_003160.3) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs751129243, COSV100249016; called by muse, mutect2, varscan2
- AURKC | c.787C>T p.P263S (on ENST00000302804 / NM_001015878.2; = p.P229S on NM_003160.3) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100248992, COSV100249018; called by muse, mutect2, varscan2
- AUTS2 | c.3517G>A p.A1173T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV100719630; called by muse, mutect2, varscan2
- AVPR1A | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100146920; called by muse, mutect2
- AVPR1B | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.165); catalogued as rs200893536, COSV65637773; called by muse, mutect2, varscan2
- AXIN1 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs143974067; called by muse, varscan2
- AXIN2 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as rs772636882, COSV61057849, COSV61060193; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AXIN2 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs748495558, COSV100197002; called by muse, mutect2, varscan2
- AZGP1 | c.174C>A p.F58L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371816790, COSV99448254; called by muse, mutect2, varscan2
- AZIN2 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99613831; called by muse, mutect2, varscan2
- B3GALNT2 | c.917A>G p.E306G | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); catalogued as COSV100782889; called by muse, mutect2, varscan2
- B3GALT5 | c.767G>T p.R256I | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.223); catalogued as COSV100563437, COSV100563496; called by muse, mutect2, varscan2
- B3GNT3 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.198); catalogued as COSV100592868; called by muse, mutect2, varscan2
- B3GNT3 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as rs773089168, COSV100592871, COSV59438734; called by muse, mutect2, varscan2
- B3GNT5 | c.455G>T p.R152M | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100194093; called by muse, mutect2, varscan2
- B3GNT9 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.234); catalogued as COSV54630208; called by muse, mutect2, varscan2
- B4GALNT3 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs775467784, COSV99843655; called by muse, varscan2
- B4GALNT3 | c.1720C>T p.R574W | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs763992260, COSV99843657; called by muse, varscan2
- B4GALNT4 | c.2869+2T>C p.X957_splice | Splice Site (SNP) | VAF 6/12 reads (50%) | catalogued as rs1351686518, COSV100327887; called by muse, mutect2, varscan2
- B4GALT3 | c.1037C>A p.P346H | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100157937; called by muse, mutect2, varscan2
- B4GALT4 | c.925T>C p.S309P | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs1340586328, COSV100785856; called by muse, mutect2, varscan2
- B4GALT6 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1332441165, COSV99380383; called by muse, mutect2
- B4GAT1 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.146); catalogued as COSV100240399; called by muse, mutect2, varscan2
- BAG6 | c.3153G>A p.W1051* (on ENST00000676571; = p.W1004* on NM_080702.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 40/97 reads (41%) | catalogued as COSV99277662; called by muse, mutect2, varscan2
- BAG6 | c.2784G>T p.Q928H (on ENST00000676571; = p.Q881H on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99277664; called by muse, mutect2, varscan2
- BAG6 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs143680960; called by muse, varscan2
- BAG6 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99277671; called by muse, varscan2
- BAHCC1 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1555652034, COSV100312097; called by muse, mutect2, varscan2
- BAHD1 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as COSV101346801; called by muse, mutect2, varscan2
- BAHD1 | c.1949C>A p.S650Y | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101346802; called by muse, mutect2, varscan2
- BAIAP2 | c.973T>C p.S325P | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); catalogued as COSV100348908; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.781); catalogued as COSV99134922; called by muse, mutect2, varscan2
- BAIAP3 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100181952, COSV60981484; called by muse, mutect2, varscan2
- BARD1 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs777089938, COSV99639977; called by muse, mutect2, varscan2
- BAZ1B | c.2864G>A p.R955H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); catalogued as rs1310053804, COSV59994327; called by muse, mutect2, varscan2
- BAZ1B | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59992821; called by muse, mutect2, varscan2
- BBS2 | c.1007A>T p.D336V | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99802873; called by muse, mutect2, varscan2
- BCAN | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.683); catalogued as COSV100228525; called by muse, mutect2, varscan2
- BCAN | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 96/107 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1245040424, COSV61258287; called by muse, mutect2, varscan2
- BCAN | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs775100384, COSV61255937; called by muse, mutect2, varscan2
- BCAR1 | c.2267C>T p.T756I | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.994); catalogued as COSV99367449; called by muse, mutect2, varscan2
- BCAR1 | c.1995C>A p.D665E | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1320875562, COSV99367452; called by muse, mutect2, varscan2
- BCAR1 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs767903911, COSV99367459; called by muse, mutect2, varscan2
- BCAT2 | c.531+1G>A p.X177_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100302562; called by muse, mutect2, varscan2
- BCAT2 | c.102T>C p.A34= | Splice Region (SNP) | VAF 23/48 reads (48%) | catalogued as rs781004194, COSV100302563, COSV60274200; called by muse, mutect2, varscan2
- BCHE | c.420G>A p.W140* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as COSV100013030; called by muse, mutect2, varscan2
- BCL11A | c.1699A>G p.T567A (on ENST00000335712 / NM_001365609.1; = p.T601A on NM_018014.4) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100186610; called by muse, mutect2, varscan2
- BCL11A | c.628C>T p.P210S (on ENST00000335712 / NM_001365609.1; = p.P244S on NM_018014.4) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs775416531, COSV100186611; called by muse, mutect2, varscan2
- BCL11B | c.2377C>T p.R793C (on ENST00000357195 / NM_001282237.2; = p.R722C on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1212566371, COSV100595966; called by muse, mutect2, varscan2
- BCL11B | c.2050G>A p.A684T (on ENST00000357195 / NM_001282237.2; = p.A613T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.034); catalogued as rs1010586637, COSV100595968; called by muse, varscan2
- BCL9 | c.3886C>T p.P1296S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.452); catalogued as COSV99325911; called by muse, varscan2
- BCL9 | c.3902A>G p.D1301G | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.161); catalogued as COSV99325912; called by muse, varscan2
- BCL9L | c.3223C>T p.P1075S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1162696175, COSV52688394, COSV99420185; called by muse, mutect2, varscan2
- BCL9L | c.3002C>T p.A1001V | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.46); catalogued as rs772911139, COSV52681937; called by muse, mutect2, varscan2
- BCL9L | c.835-1G>T p.X279_splice | Splice Site (SNP) | VAF 6/10 reads (60%) | catalogued as rs1486273719, COSV100600249; called by muse, varscan2
- BCR | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as rs371224222; called by muse, mutect2, varscan2
- BCS1L | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV99829237; called by muse, mutect2, varscan2
- BDKRB2 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186789152, COSV100021495; called by muse, mutect2, varscan2
- BDP1 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1382373385, COSV100703584; called by muse, mutect2, varscan2
- BECN1 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.301); catalogued as rs763193803, COSV100162206; called by muse, mutect2, varscan2
- BEND4 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101549803; called by muse, mutect2
- BEND7 | c.716T>G p.F239C | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100347075; called by muse, mutect2, varscan2
- BFSP2 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100183969; called by muse, mutect2, varscan2
- BHLHE40 | c.998C>A p.T333N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV99848311; called by muse, mutect2, varscan2
- BHMT | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs776825529, COSV99165548; called by muse, mutect2, varscan2
- BHMT | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV57154456; called by muse, mutect2, varscan2
- BICD2 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100794093; called by muse, mutect2, varscan2
- BMP1 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.274); catalogued as rs561063512, COSV100110178, COSV60476566; called by muse, mutect2, varscan2
- BMP1 | c.1673G>A p.G558D | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs1167149114, COSV100110180; called by muse, mutect2, varscan2
- BMP2 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1258528022, CM1514288, COSV101122122; called by muse, mutect2, varscan2
- BMP2 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV101122123; called by muse, mutect2, varscan2
- BMP5 | c.1241T>C p.V414A | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100896377; called by muse, mutect2, varscan2
- BMPER | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1043861409, COSV51814238; called by muse, mutect2, varscan2
- BMPR1A | c.833A>G p.Y278C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100923719; called by muse, mutect2, varscan2
- BMS1 | c.3295C>T p.R1099* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as rs1213981443, COSV100996834; called by muse, mutect2, varscan2
- BMS1 | c.3598C>T p.R1200C | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs748630867, COSV65733941, COSV65735414; called by muse, mutect2, varscan2
- BMT2 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.716); catalogued as COSV51778173; called by muse, mutect2, varscan2
- BNC2 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV101034585; called by muse, mutect2, varscan2
- BNIP5 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs758606753, COSV101465217; called by muse, mutect2, varscan2
- BOD1L1 | c.1238C>T p.T413I | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1324336191, COSV99240502; called by muse, mutect2, varscan2
- BOP1 | c.2218G>A p.G740R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1020723782; called by muse, mutect2, varscan2
- BPI | c.384C>A p.F128L (on ENST00000262865; = p.F124L on NM_001725.3) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.208); catalogued as COSV99480990; called by muse, mutect2, varscan2
- BPIFB1 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV99487620; called by muse, mutect2, varscan2
- BPIFB3 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1486001052, COSV64957674; called by muse, mutect2, varscan2
- BRCA2 | c.6825G>T p.E2275D | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV101204671; called by muse, mutect2, varscan2
- BRD1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156918290, COSV99350356; called by muse, mutect2, varscan2
- BRD2 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as rs771459465, COSV66374414; called by muse, mutect2, varscan2
- BRF2 | c.270G>T p.E90D | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV99605161; called by muse, mutect2, varscan2
- BRINP2 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1381540190, COSV100838483; called by muse, mutect2, varscan2
- BRINP2 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs764207765, COSV64178147; called by muse, varscan2
- BRIP1 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs1184306036, COSV99371172; called by muse, mutect2, varscan2
- BRMS1 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs755639797, COSV60819706, COSV60820394; called by muse, mutect2, varscan2
- BRPF1 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs781235866, COSV57405813; called by muse, mutect2, varscan2
- BRSK1 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs770130862, COSV100474696; called by mutect2, varscan2
- BRSK1 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1360413273, COSV58665747; called by muse, mutect2, varscan2
- BRWD1 | c.6293G>A p.G2098D | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs1191456949, COSV100314232; called by muse, mutect2, varscan2
- BRWD1 | c.3919del p.S1307Afs*19 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs1296036169; called by mutect2, pindel, varscan2
- BSCL2 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV99628548; called by muse, mutect2, varscan2
- BSN | c.4877C>T p.P1626L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99609940; called by muse, mutect2, varscan2
- BSN | c.6661C>T p.R2221C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1459432853, COSV56514466; called by muse, mutect2, varscan2
- BTAF1 | c.3076G>T p.G1026* | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | catalogued as COSV99795882; called by muse, mutect2, varscan2
- BTBD11 | c.1682C>T p.A561V (on ENST00000280758 / NM_001018072.2; = p.A98V on NM_001017523.2) | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1368588123, COSV55016681; called by muse, mutect2, varscan2
- BTBD2 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV99724979; called by muse, varscan2
- BTBD2 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.223); catalogued as rs1235842458, COSV99724982; called by muse, varscan2
- BTG3 | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.99); catalogued as rs756169731, COSV100336310; called by muse, mutect2, varscan2
- BTN2A2 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as rs1156599160, COSV61859277; called by muse, mutect2, varscan2
- BTNL2 | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV100896221; called by muse, mutect2, varscan2
- BTRC | c.232C>T p.Q78* (on ENST00000370187 / NM_033637.4; = p.Q42* on NM_003939.5) | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100926633; called by muse, mutect2, varscan2
- BTRC | c.905C>T p.T302I (on ENST00000370187 / NM_033637.4; = p.T266I on NM_003939.5) | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV100927937; called by muse, mutect2, varscan2
- BUB1B | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 24/74 reads (32%) | catalogued as COSV55013917, COSV99807353; called by muse, mutect2, varscan2
- BUB1B | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs552380700, COSV55016219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BUB1B | c.3131C>A p.P1044H | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV99807359; called by muse, mutect2, varscan2
- BUD13 | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755391430, COSV52770888; called by muse, mutect2, varscan2
- BZW1 | c.854dup p.N285Kfs*54 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | catalogued as rs774640795; called by mutect2, varscan2
- C11orf16 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100393902; called by mutect2, varscan2
- C11orf16 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1195841544, COSV100393904; called by muse, mutect2, varscan2
- C11orf24 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV100422440; called by muse, mutect2, varscan2
- C11orf53 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as rs376710383; called by muse, mutect2, varscan2
- C12orf40 | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as rs1469049887, COSV100210821; called by muse, mutect2, varscan2
- C12orf42 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs774618246, COSV59386564; called by muse, mutect2, varscan2
- C14orf93 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs201600502, COSV54442408; called by muse, mutect2, varscan2
- C16orf89 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.44); catalogued as rs532111292, COSV100280997; called by muse, mutect2, varscan2
- C17orf97 | c.1222C>T p.L408F | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.278); catalogued as COSV100789396; called by muse, mutect2, varscan2
- C18orf25 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs759702161, COSV99960237; called by muse, varscan2
- C19orf47 | c.440T>G p.L147R | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100775181; called by muse, mutect2, varscan2
- C1GALT1C1L | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs367551441; called by muse, mutect2, varscan2
- C1QB | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs1173621013, COSV59245263; called by muse, mutect2, varscan2
- C1QTNF12 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as rs200792498, COSV100382647; called by muse, varscan2
- C1QTNF6 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201178136, COSV99742425; called by muse, mutect2, varscan2
- C1orf146 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753716244, COSV100950216; called by muse, mutect2, varscan2
- C1orf194 | c.178G>A p.A60T (on ENST00000369948 / NM_001245025.3; = p.A48T on NM_001122961.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100885202; called by muse, mutect2, varscan2
- C1orf87 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100967264; called by muse, mutect2, varscan2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, pindel
- C22orf31 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99326532; called by muse, mutect2, varscan2
- C22orf42 | c.566G>C p.S189T | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.294); catalogued as rs752995379, COSV101173389, COSV66075951; called by muse, mutect2, varscan2
- C2CD2 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100298441; called by muse, mutect2, varscan2
- C2CD2L | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1301278615, COSV100371506; called by muse, mutect2, varscan2
- C2CD2L | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1332909682, COSV100371507; called by muse, mutect2, varscan2
- C2CD3 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV100487491, COSV100487679; called by muse, mutect2, varscan2
- C2orf49 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs764172396, COSV51527486; called by muse, mutect2, varscan2
- C2orf73 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs970554369, COSV100471522; called by muse, varscan2
- C2orf73 | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1256917896, COSV100471523; called by muse, varscan2
- C3 | c.1876G>A p.G626S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as rs777836973, COSV99837312; called by muse, mutect2, varscan2
- C3AR1 | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs745562405, COSV50817474; called by muse, mutect2, varscan2
- C3orf18 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as rs773868596, COSV100597228; called by muse, mutect2, varscan2
- C3orf20 | c.1434G>T p.K478N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99514611; called by muse, mutect2, varscan2
- C3orf20 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs149516015, COSV99514624; called by muse, mutect2, varscan2
- C4orf19 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99448807; called by muse, mutect2, varscan2
- C5 | c.4373G>A p.G1458E | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV56332642; called by muse, mutect2, varscan2
- C5AR2 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.453); catalogued as rs767179541, COSV57255459; called by muse, mutect2, varscan2
- C5orf51 | c.694A>C p.N232H | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV101069075; called by muse, mutect2, varscan2
- C6orf118 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.453); catalogued as COSV100025209; called by muse, mutect2, varscan2
- C7orf50 | c.132C>T p.G44= | Splice Region (SNP) | VAF 4/24 reads (17%) | catalogued as rs755489999, COSV62473605; called by mutect2, varscan2
- C8A | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs773507337; called by muse, varscan2
- C8A | c.485A>T p.E162V | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV100776671; called by muse, mutect2, varscan2
- C8A | c.1098T>C p.G366= | Splice Region (SNP) | VAF 59/146 reads (40%) | catalogued as COSV100776672; called by muse, mutect2, varscan2
- C8orf58 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs769696478, COSV51514782, COSV51515153; called by muse, mutect2, varscan2
- C9 | c.476+1G>A p.X159_splice | Splice Site (SNP) | VAF 15/51 reads (29%) | catalogued as COSV99662609; called by muse, mutect2, varscan2
- C9orf78 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100204810; called by muse, mutect2, varscan2
- CA13 | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.129); catalogued as COSV58799023; called by muse, mutect2, varscan2
- CA4 | c.654C>A p.F218L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV99958522; called by muse, mutect2, varscan2
- CA8 | c.304G>T p.G102* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as rs1407877780, COSV100527327; called by muse, mutect2, varscan2
- CABP1 | c.764G>A p.R255H (on ENST00000316803 / NM_001033677.1; = p.R52H on NM_004276.5) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747880479, COSV56458162; called by mutect2, varscan2
- CABP4 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100351432; called by muse, mutect2, varscan2
- CACNA1A | c.5011G>A p.A1671T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV100803293; called by muse, mutect2, varscan2
- CACNA1A | c.4138G>A p.V1380I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV64195621; called by muse, mutect2, varscan2
- CACNA1B | c.3449G>A p.R1150K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV99500075; called by muse, mutect2, varscan2
- CACNA1C | c.1466G>A p.C489Y | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV100222597; called by muse, mutect2
- CACNA1E | c.1211C>T p.T404I | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.4); catalogued as rs1286947164, COSV100705542; called by muse, mutect2, varscan2
- CACNA1E | c.3526G>A p.V1176I | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.48); catalogued as rs1228218600, COSV62382262; called by muse, mutect2, varscan2
- CACNA1G | c.5002C>T p.R1668C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1369128414, COSV61730920; called by muse, mutect2, varscan2
- CACNA1G | c.5095G>A p.A1699T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV61721223; called by muse, mutect2, varscan2
- CACNA1H | c.5209G>A p.A1737T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs61372944, COSV100673569; called by mutect2, varscan2
- CACNA1I | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100361656; called by muse, mutect2, varscan2
- CACNA2D2 | c.3272A>G p.Y1091C (on ENST00000479441 / NM_001174051.3; = p.Y1084C on NM_006030.4) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99818425; called by muse, mutect2, varscan2
- CACNA2D2 | c.2503C>T p.R835C (on ENST00000479441 / NM_001174051.3; = p.R828C on NM_006030.4) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs774552132, COSV56567796; called by muse, mutect2, varscan2
- CACNG1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs372713806, COSV99871790; called by muse, mutect2, varscan2
- CACTIN | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs866352473, COSV99698827; called by muse, mutect2, varscan2
- CAD | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.332); catalogued as rs753774023, COSV99255829; called by muse, mutect2, varscan2
- CAD | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV99255834; called by muse, varscan2
- CAD | c.4531A>G p.I1511V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV99255842; called by muse, mutect2, varscan2
- CAD | c.4889G>A p.R1630Q | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs375486999, COSV53030814; called by muse, mutect2, varscan2
- CAD | c.6301C>A p.L2101M | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV99255847; called by muse, mutect2, varscan2
- CADM2 | c.188C>T p.T63I (on ENST00000407528 / NM_001167674.2; = p.T65I on NM_153184.4) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1181008791, COSV101059627; called by muse, mutect2, varscan2
- CADPS | c.3985G>A p.A1329T | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV51870631; called by muse, mutect2, varscan2
- CALCOCO2 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs771231561, COSV99363962; called by muse, mutect2, varscan2
- CALCR | c.739G>A p.A247T (on ENST00000649521 / NM_001164737.2; = p.A231T on NM_001742.4) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1373845709, COSV100810891, COSV64005728; called by muse, mutect2, varscan2
- CALHM2 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as rs1264709383, COSV53296067; called by muse, mutect2, varscan2
- CALHM5 | c.738dup p.E247* | Frame Shift Ins (INS) | VAF 17/72 reads (24%) | catalogued as rs768528441; called by mutect2, varscan2
- CALM1 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.087); catalogued as rs1199451414, COSV100811174; called by muse, mutect2, varscan2
- CALML3 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.029); catalogued as rs1404095356, COSV100178912; called by muse, mutect2, varscan2
- CALU | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs150941182; called by muse, mutect2, varscan2
- CAMK1 | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99844979; called by muse, mutect2, varscan2
- CAMK2D | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | catalogued as rs778447492, COSV99594889; called by muse, mutect2, varscan2
- CAMK4 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100000397; called by muse, mutect2, varscan2
- CAMK4 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV100000398; called by muse, mutect2, varscan2
- CAMSAP1 | c.4010G>A p.R1337H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1386838221, COSV56720748; called by muse, varscan2
- CAMSAP1 | c.948G>T p.K316N | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100410471; called by muse, mutect2, varscan2
- CAND2 | c.2926C>T p.R976W (on ENST00000456430 / NM_001162499.2; = p.R883W on NM_012298.3) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs770646822, COSV55989752; called by muse, mutect2, varscan2
- CAPN1 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756980532, COSV99658839; called by muse, mutect2, varscan2
- CAPN10 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs748756061, COSV99550582; called by muse, mutect2, varscan2
- CAPN11 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101291957; called by muse, mutect2
- CAPN11 | c.1734A>G p.I578M | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV101291958; called by muse, mutect2, varscan2
- CAPN2 | c.1272G>T p.E424D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.141); catalogued as COSV99689295; called by mutect2, varscan2
- CAPNS1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs1373988909, COSV99874718; called by muse, mutect2, varscan2
- CAPRIN1 | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.266); catalogued as COSV100404325; called by muse, mutect2, varscan2
- CAPRIN2 | c.733T>C p.Y245H | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV99195722; called by muse, mutect2
- CAPS | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774570196, COSV99222527; called by muse, mutect2, varscan2
- CAPS2 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs764447136, COSV60826315; called by muse, mutect2, varscan2
- CAPZA3 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as rs15547; called by muse, mutect2, varscan2
- CARD11 | c.2479C>A p.L827M | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100829346; called by muse, mutect2, varscan2
- CARD11 | c.2009C>T p.T670M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs3735134, COSV62754906; called by muse, mutect2, varscan2
- CARD11 | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100712289, COSV62719913; called by muse, mutect2, varscan2
- CARD14 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100712627; called by muse, mutect2, varscan2
- CARD6 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV99621348; called by muse, mutect2, varscan2
- CARM1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV100499109; called by muse, mutect2
- CARM1 | c.1546A>G p.T516A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV99450363; called by muse, mutect2, varscan2
- CARMIL1 | c.3736C>T p.R1246W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs368129452, COSV61514564; called by muse, mutect2, varscan2
- CARMIL2 | c.3500G>A p.R1167H | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs778212007, COSV99538011; called by muse, mutect2, varscan2
- CARMIL3 | c.2657G>A p.R886Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as rs763222738, COSV57725186; called by muse, mutect2, varscan2
- CARMIL3 | c.2939G>A p.R980H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1566542227; called by mutect2, varscan2
- CARS1 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53457759; called by muse, mutect2, varscan2
- CASKIN1 | c.4132G>A p.A1378T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.995); catalogued as COSV100399872; called by muse, mutect2
- CASP10 | c.1221G>T p.Q407H (on ENST00000272879 / NM_032974.5; = p.Q364H on NM_001230.5) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV99629349; called by muse, mutect2, varscan2
- CASP8 | c.790C>T p.H264Y (on ENST00000432109 / NM_033355.3; = p.H281Y on NM_001228.4) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV51851716, COSV99966092; called by muse, mutect2, varscan2
- CASP8AP2 | c.2875G>T p.V959L | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV99387597; called by muse, mutect2
- CASP9 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV100423980; called by muse, mutect2, varscan2
- CASR | c.2432C>T p.T811M (on ENST00000490131; = p.T888M on NM_000388.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as CM111189, COSV56135678; called by muse, mutect2, varscan2
- CASZ1 | c.4417C>T p.H1473Y | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV100985816; called by muse, mutect2, varscan2
- CASZ1 | c.1711C>T p.H571Y | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100682218; called by muse, mutect2, varscan2
- CATSPER3 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99254343; called by muse, mutect2, varscan2
- CATSPER4 | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.454); catalogued as COSV100128551; called by muse, mutect2, varscan2
- CATSPERD | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs1475011855, COSV67534362; called by muse, mutect2, varscan2
- CATSPERG | c.3077C>T p.A1026V | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV99286959; called by muse, mutect2, varscan2
- CAVIN1 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100824610; called by muse, mutect2, varscan2
- CAVIN2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV58426310; called by muse, mutect2, varscan2
- CBFA2T2 | c.694A>G p.N232D | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV100656539; called by muse, mutect2, varscan2
- CBLB | c.2794G>A p.V932I | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.992); catalogued as COSV99912777, COSV99914437; called by muse, mutect2, varscan2
- CBLC | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as rs201807125, COSV54326310; called by muse, mutect2
- CBLL2 | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV100081772; called by muse, mutect2, varscan2
- CBLN3 | c.503C>A p.S168Y | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99250148; called by muse, mutect2, varscan2
- CBWD2 | c.11C>G p.A4G | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV99380847; called by muse, mutect2, varscan2
7,493 further variants in this file (5,010 protein-altering or splice-affecting, 2,306 silent, 177 other) are not listed here.
